Somatic mutation profile of tumor specimen C3L-00583-02 (aliquot CPT0019140009) from CPTAC case C3L-00583, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G3; Age at diagnosis: 55.4 years (20,237 days).
Specimen C3L-00583-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3113b754-ff20-4e4d-8afc-ceb04af882ad.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-00583-31 (Blood Derived Normal), aliquot CPT0019900002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f92400cf-811e-4e6c-9557-05635258cacc

The open-access MAF lists 61 somatic variants for this specimen: 42 protein-altering or splice-affecting, 11 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 34, Silent 11, Intron 4, Frame Shift Del 3, Splice Site 2, Frame Shift Ins 2, 5'UTR 1, 5'Flank 1, RNA 1, 3'Flank 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- VHL | c.343C>T p.H115Y | Missense Mutation (SNP) | VAF 102/190 reads (54%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as rs5030811, CD141839, CM961423, CM982005, COSV56545369, COSV56546151, COSV56556158, COSV56571206; called by muse, mutect2, varscan2
- ADAMTS12 | c.3860A>C p.E1287A | Missense Mutation (SNP) | VAF 140/451 reads (31%) | SIFT tolerated (0.35); PolyPhen benign (0.211); catalogued as rs1404984152, COSV100710369; called by muse, mutect2, varscan2
- CSMD2 | c.5636C>A p.S1879Y | Missense Mutation (SNP) | VAF 47/159 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV53962655; called by muse, mutect2, varscan2
- FUT6 | c.58C>G p.L20V | Missense Mutation (SNP) | VAF 42/188 reads (22%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.582); catalogued as COSV54606589; called by muse, mutect2, varscan2
- GCNT2 | c.263T>C p.L88P | Missense Mutation (SNP) | VAF 42/426 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.735); catalogued as rs143453847; called by muse, mutect2, varscan2
- GNRHR | c.869A>T p.Y290F | Missense Mutation (SNP) | VAF 56/177 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as CM1111643; called by muse, mutect2, varscan2
- KDM5C | c.826G>T p.E276* | Nonsense Mutation (SNP) | VAF 86/168 reads (51%) | catalogued as COSV64763119; called by muse, mutect2, varscan2
- MTOR | c.7292T>A p.L2431Q | Missense Mutation (SNP) | VAF 31/103 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63868562; called by muse, mutect2, varscan2
- NPSR1 | c.53C>T p.T18M | Missense Mutation (SNP) | VAF 47/318 reads (15%) | SIFT tolerated (0.21); PolyPhen benign (0.006); catalogued as rs149663215; called by muse, mutect2, varscan2
- ZNF787 | c.1109G>A p.G370D | Missense Mutation (SNP) | VAF 27/81 reads (33%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0); catalogued as rs1174903192; called by muse, mutect2, varscan2
- ACACB | c.1630T>C p.F544L | Missense Mutation (SNP) | VAF 106/358 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- ATE1 | c.1461del p.K487Nfs*60 | Frame Shift Del (DEL) | VAF 71/281 reads (25%) | called by mutect2, pindel, varscan2
- BBOF1 | c.187del p.S63Vfs*5 | Frame Shift Del (DEL) | VAF 25/116 reads (22%) | called by mutect2, pindel, varscan2
- BLOC1S3 | c.409C>A p.R137S | Missense Mutation (SNP) | VAF 60/178 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.35); called by muse, mutect2, varscan2
- BRWD1 | c.56A>T p.Y19F | Missense Mutation (SNP) | VAF 83/259 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.405); called by muse, mutect2, varscan2
- BTG4 | c.202A>C p.K68Q | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT tolerated (0.51); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- COL8A2 | c.383C>T p.P128L | Missense Mutation (SNP) | VAF 28/170 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.478); called by muse, mutect2, varscan2
- CSE1L | c.80G>T p.R27L | Missense Mutation (SNP) | VAF 50/173 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.919); called by muse, mutect2, varscan2
- CTNNA2 | c.2602G>T p.A868S (on ENST00000402739 / NM_001282597.3; = p.A820S on NM_004389.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/79 reads (27%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.588); called by muse, mutect2, varscan2
- CYP51A1 | c.549dup p.E184Rfs*7 | Frame Shift Ins (INS) | VAF 43/242 reads (18%) | called by pindel, varscan2
- DNAJB13 | c.167G>C p.S56T | Missense Mutation (SNP) | VAF 50/159 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- DRICH1 | c.496G>T p.D166Y | Missense Mutation (SNP) | VAF 40/327 reads (12%) | SIFT tolerated, low confidence (0.15); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- FANCM | c.1432dup p.R478Pfs*11 | Frame Shift Ins (INS) | VAF 32/148 reads (22%) | called by pindel, varscan2
- FBN3 | c.1399C>T p.P467S | Missense Mutation (SNP) | VAF 25/96 reads (26%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.902); called by muse, mutect2, varscan2
- GBP5 | c.1060C>G p.L354V | Missense Mutation (SNP) | VAF 98/381 reads (26%) | SIFT tolerated (0.41); PolyPhen benign (0.268); called by muse, mutect2, varscan2
- GCN1 | c.7563+1G>A p.X2521_splice | Splice Site (SNP) | VAF 51/109 reads (47%) | called by muse, mutect2, varscan2
- GOLGA8J | c.1158G>C p.Q386H | Missense Mutation (SNP) | VAF 68/628 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.154); called by muse, mutect2, varscan2
- HMGCR | c.141T>G p.N47K | Missense Mutation (SNP) | VAF 70/193 reads (36%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.448); called by muse, mutect2, varscan2
- IMPG1 | c.1762A>C p.N588H | Missense Mutation (SNP) | VAF 40/112 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.171); called by muse, mutect2, varscan2
- IPO9 | c.389A>G p.Y130C | Missense Mutation (SNP) | VAF 128/374 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- LINC02868 | n.87-1G>T | Splice Site (SNP) | VAF 41/143 reads (29%) | called by muse, mutect2, varscan2
- MTOR | c.7291C>A p.L2431M | Missense Mutation (SNP) | VAF 31/101 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MTREX | c.559_562del p.F187Pfs*7 | Frame Shift Del (DEL) | VAF 27/87 reads (31%) | called by mutect2, pindel, varscan2
- NOTCH4 | c.1732C>T p.L578F | Missense Mutation (SNP) | VAF 19/194 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.04); called by muse, mutect2
- PBRM1 | c.2264T>A p.V755D | Missense Mutation (SNP) | VAF 39/66 reads (59%) | SIFT deleterious (0); PolyPhen possibly damaging (0.667); called by muse, mutect2, varscan2
- PCDHB10 | c.1941T>A p.N647K | Missense Mutation (SNP) | VAF 308/1024 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.969); called by muse, varscan2
- SMC1B | c.238G>A p.V80I | Missense Mutation (SNP) | VAF 10/167 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); called by muse, mutect2
- SPEG | c.7274G>C p.R2425P | Missense Mutation (SNP) | VAF 48/179 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TFAM | c.178T>A p.F60I | Missense Mutation (SNP) | VAF 164/460 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- TMEM131 | c.3836A>T p.K1279M | Missense Mutation (SNP) | VAF 65/217 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.707); called by muse, mutect2, varscan2
- VWA8 | c.5639C>G p.S1880C | Missense Mutation (SNP) | VAF 48/139 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- WDR86 | c.306G>T p.R102S | Missense Mutation (SNP) | VAF 79/346 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- CALML5 | c.159C>T p.I53= | Silent (SNP) | VAF 151/470 reads (32%) | catalogued as rs1323376519; called by muse, mutect2, varscan2
- DNAI3 | c.1428T>C p.N476= | Silent (SNP) | VAF 49/154 reads (32%) | catalogued as rs1225726526; called by muse, mutect2, varscan2
- EBAG9 | c.132T>C p.T44= | Silent (SNP) | VAF 34/116 reads (29%) | catalogued as rs1312285780; called by muse, mutect2, varscan2
- GPC4 | c.684G>A p.A228= | Silent (SNP) | VAF 27/54 reads (50%) | catalogued as rs757883865; called by muse, mutect2, varscan2
- KRT15 | c.288C>T p.G96= | Silent (SNP) | VAF 59/229 reads (26%) | catalogued as rs768785185; called by muse, mutect2, varscan2
- MUC5AC | c.14839C>T p.L4947= | Silent (SNP) | VAF 121/394 reads (31%) | called by muse, mutect2, varscan2
- MYCBP2 | c.5061T>C p.A1687= (on ENST00000357337; = p.A1725= on NM_015057.5) | Silent (SNP) | VAF 80/294 reads (27%) | called by muse, mutect2, varscan2
- PCF11 | c.4653A>G p.T1551= | Silent (SNP) | VAF 27/82 reads (33%) | called by muse, mutect2, varscan2
- TNKS | c.870T>C p.A290= | Silent (SNP) | VAF 68/199 reads (34%) | called by muse, mutect2, varscan2
- TPTE | c.312G>C p.L104= (on ENST00000618007 / NM_199261.4; = p.L86= on NM_199259.4) | Silent (SNP) | VAF 67/291 reads (23%) | called by muse, mutect2, varscan2
- UNC13B | c.4206C>T p.I1402= | Silent (SNP) | VAF 72/123 reads (59%) | called by muse, mutect2, varscan2
- ATL2 | c.118+1025T>A | Intron (SNP) | VAF 6/12 reads (50%) | catalogued as rs143781075; called by muse, mutect2
- DNAH14 | c.2938+1982A>G | Intron (SNP) | VAF 52/165 reads (32%) | called by muse, mutect2, varscan2
- EHD4 | chr15:41895292 C>T | 3'Flank (SNP) | VAF 30/128 reads (23%) | called by muse, mutect2
- ERLIN2 | chr8:37736077 A>T | 5'Flank (SNP) | VAF 14/46 reads (30%) | called by muse, mutect2, varscan2
- HSPB1 | c.-14C>T | 5'UTR (SNP) | VAF 184/575 reads (32%) | called by muse, mutect2, varscan2
- NACA | c.71-2028G>A | Intron (SNP) | VAF 4/22 reads (18%) | catalogued as COSV63271385; called by muse, mutect2, varscan2
- OPLAH | c.2512-33C>T | Intron (SNP) | VAF 101/364 reads (28%) | catalogued as rs1279438708; called by muse, mutect2, varscan2
- SPATA31C2 | n.1939del | RNA (DEL) | VAF 200/597 reads (34%) | called by mutect2, pindel, varscan2
